TCGA case TCGA-D7-6520 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Greater Poland Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3c573af6-6298-49de-8de0-6a7f9ce9b000

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: Poland; Age at index: 53 years; Vital status: Alive.

Diagnoses (2)
1. Tubular adenocarcinoma (the primary disease): ICD-O-3 morphology code: 8211/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 53.3 years (19,467 days); Year of diagnosis: 2010; AJCC staging edition: 6th; AJCC pathologic T: T2b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 573 days (1.6 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 14; Lymph nodes tested: 24.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Capecitabine; Days to treatment start: 53 days; Days to treatment end: 172 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Epirubicin + Oxaliplatin; Initial disease status: Progressive Disease; Days to treatment start: 53 days; Days to treatment end: 172 days; Number of cycles: 6; Prescribed dose: 87.5; Prescribed dose units: mg; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Dexamethasone Phosphate + Docetaxel + Fluorouracil; Days to treatment start: 249 days; Days to treatment end: 321 days; Treatment outcome: Progressive Disease.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Metastasis of diagnosis 1 (Tubular adenocarcinoma), site: Liver. Age at diagnosis: 53.4 years (19,513 days); Days to diagnosis: 46 days; Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Surgery, NOS to Distant Site.

Follow-up (3 entries)
- Day 46 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 46 days; Evidence of progression type: Convincing Image Source.
- Days to follow up: 573 days (1.6 years); Disease response: With Tumor.
- Follow-up contact recording only the day: day 293.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-D7-6520-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Longest dimension: 1.1; Intermediate dimension: 0.5; Shortest dimension: 0.5.
  Slide TCGA-D7-6520-01A-01-BS1: Section location: Bottom; Percent tumor cells: 85; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 15.
  Slide TCGA-D7-6520-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
- Sample TCGA-D7-6520-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-D7-6520-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach, Intestinal Adenocarcinoma, Tubular Type; History neoadjuvant treatment: No; Prospective collection: Yes; Retrospective collection: No; Anatomic organ subdivision: Antrum/Distal; Lymph nodes examined: Yes; Cancer procurement city: Poznan; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No.
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 1, Route of administrations: Route of administration: IV.
- Drug treatment 2: Pharmaceutical therapy drug name: Cisplatinum; Treatment best response: Clinical Progressive Disease.
- Drug treatment 4: Pharmaceutical therapy drug name: Capecytabinum.
- Drug treatment 6: Pharmaceutical therapy drug name: Docetaxelum; Treatment best response: Clinical Progressive Disease.
- Drug treatment 7: Pharmaceutical therapy drug name: Fluorouracilum; Treatment best response: Clinical Progressive Disease.
- Follow-up form: Tumor status: With tumor; New tumor event radiation treatment: Yes; New tumor event pharmaceutical treatment: Yes; New tumor event surgery met: No.
- Follow-up form, Progression determined by list: New tumor event diagnosis evidence: Convincing Imaging.
- Follow-up form, New neoplasm event types: New tumor event type: Distant Metastasis.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 573 days; disease-specific survival: no event (censored), 573 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 46 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-D7-6520-01A-11D-1799-01): tumor purity 0.52, ploidy 3.86, whole-genome doublings 1.
